CPTAC case C3L-00006 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bd69e879-9ee0-415d-90ef-ccddd9feaf92

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1951; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Endometrium; Age at diagnosis: 64.9 years (23,700 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 737 days (2.0 years); Progression or recurrence: no; Days to last follow up: 737 days (2.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.9 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 31; Margin status: Uninvolved.

Follow-up (4 entries)
- Days to follow up: 494 days (1.4 years); Disease response: Tumor Free.
- Days to follow up: 717 days (2.0 years); Disease response: Tumor Free.
- Days to follow up: 737 days (2.0 years); Disease response: Complete Response.
- Days to follow up: 737 days (2.0 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 90.3 kg; Height: 152.4 cm; BMI: 38.88; Comorbidities: Sleep Apnea.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 5; Cigarettes per day: 20; Tobacco smoking onset year: 1971; Tobacco smoking quit year: 1976; Exposure duration years: 5.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00006-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 309 mg; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00006-21: Section location: Anterior endometrium; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-00006-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 343 mg; Time between excision and freezing: 13 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00006-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00006-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 1 day; Method of sample procurement: Blood Draw.
